CCDI case PBBVRI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4afc8d8e-1c81-4ace-b033-82d5ce067d04

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 23.2 years (8,480 days).

Biospecimens (3 samples)
- Sample 0DK83R: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DK83X: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK842: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
